Somatic mutation profile of tumor specimen TCGA-61-2611-02A (aliquot TCGA-61-2611-02A-01W-1092-09) from TCGA case TCGA-61-2611, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.5 years (14,782 days).
Specimen TCGA-61-2611-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2300aa7e-b718-407d-bf14-99f06c1d3aee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2611-11A (Solid Tissue Normal), aliquot TCGA-61-2611-11A-01W-1092-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87b9cbfc-f58e-421e-8532-9ff45cd80c67

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 3, Splice Site 1, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773796963, COSV56023629; called by muse, mutect2, varscan2
- ADCY1 | c.1899-1G>T p.X633_splice | Splice Site (SNP) | VAF 29/474 reads (6%) | catalogued as COSV99812516, COSV99813117; called by muse, mutect2
- AMPD1 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.877); catalogued as rs767292629, COSV100815138; called by muse, mutect2
- ANKRD50 | c.2770G>A p.G924R | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760277714, COSV72386273; called by muse, mutect2, varscan2
- APOB | c.9784C>T p.P3262S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.247); catalogued as COSV51951370; called by muse, mutect2, varscan2
- BCAS1 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1568894755, COSV101006048, COSV65089204; called by muse, mutect2, varscan2
- CLCN1 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs760323048, COSV100578290, COSV58367907; called by muse, mutect2
- CLK1 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 73/524 reads (14%) | catalogued as COSV58435802; called by muse, mutect2, varscan2
- COL4A1 | c.3821C>T p.P1274L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101011344; called by mutect2, varscan2
- EML4 | c.2114C>A p.S705Y | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100581058; called by muse, mutect2
- EP400 | c.4275C>T p.S1425= | Splice Region (SNP) | VAF 16/53 reads (30%) | catalogued as rs1329234727, COSV57785790; called by muse, mutect2, varscan2
- EPN1 | c.1426G>C p.G476R (on ENST00000270460 / NM_001321263.1; = p.G450R on NM_013333.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50044282; called by muse, mutect2, varscan2
- ESF1 | c.516T>G p.I172M | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.101); catalogued as COSV52524175; called by muse, mutect2, varscan2
- FBXO9 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | catalogued as COSV55057149; called by mutect2, varscan2
- FSIP2 | c.17470C>G p.L5824V | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58099121; called by muse, mutect2, varscan2
- HDAC8 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65228076; called by muse, mutect2, varscan2
- IPO13 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV64895005; called by muse, mutect2, varscan2
- KLF12 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100888558; called by muse, mutect2
- MCAM | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.081); catalogued as COSV50662416; called by muse, mutect2, varscan2
- NCKAP5L | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.251); catalogued as COSV100259002; called by muse, mutect2
- PAXIP1 | c.298T>G p.F100V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.727); catalogued as COSV68187732; called by muse, mutect2, varscan2
- PCSK9 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV56161729; called by muse, mutect2
- PLA1A | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56333750; called by muse, mutect2, varscan2
- PRPF38B | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 19/543 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100898307; called by muse, mutect2
- PTPN14 | c.1361G>T p.R454M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100872806; called by mutect2, varscan2
- S1PR2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58485849; called by muse, mutect2, varscan2
- SIDT2 | c.185C>G p.T62R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV99638111; called by muse, mutect2
- SMTNL1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV101216478, COSV101216616; called by muse, mutect2
- SPTBN1 | c.5026G>A p.V1676M | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100443060; called by muse, mutect2
- TBCCD1 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs780610943, COSV100112059; called by muse, mutect2
- TFRC | c.1695T>A p.Y565* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV64056411; called by muse, mutect2, varscan2
- TMEM161A | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV50777866; called by muse, mutect2, varscan2
- TRIM29 | c.1684T>C p.S562P | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100531823; called by muse, mutect2
- TTC39C | c.439T>C p.F147L (on ENST00000317571 / NM_001135993.2; = p.F86L on NM_153211.4) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.721); catalogued as COSV100455493; called by mutect2, varscan2
- TTF1 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV57507245; called by muse, mutect2, varscan2
- USP47 | c.798G>T p.E266D (on ENST00000399455 / NM_001372095.1; = p.E178D on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV60467792; called by muse, mutect2, varscan2
- VRTN | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99832348; called by muse, mutect2
- VWA5A | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.217); catalogued as COSV63708103, COSV63708263; called by muse, mutect2, varscan2
- XIRP1 | c.4099G>T p.D1367Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as COSV100453799; called by muse, mutect2, varscan2
- CHGA | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- RABGAP1 | c.1744_1747del p.C582Ifs*7 | Frame Shift Del (DEL) | VAF 8/100 reads (8%) | called by mutect2, pindel
- CGAS | c.1425C>A p.L475= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV64809006; called by muse, mutect2, varscan2
- DCLRE1A | c.1335G>A p.Q445= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs1255230124, COSV63749076; called by muse, mutect2
- FASTKD5 | c.2256G>A p.L752= | Silent (SNP) | VAF 25/218 reads (11%) | catalogued as COSV53909455; called by muse, mutect2, varscan2
- JPH2 | c.1038G>A p.L346= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100881777; called by muse, mutect2
- MED13 | c.2706C>G p.V902= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV67266934; called by muse, mutect2, varscan2
- POLR1A | c.897A>G p.L299= | Silent (SNP) | VAF 17/288 reads (6%) | catalogued as COSV99808097; called by muse, mutect2
- PREX2 | c.2205C>G p.V735= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV55760887, COSV99908618; called by muse, mutect2
- SEMA3A | c.1245T>A p.P415= | Silent (SNP) | VAF 24/350 reads (7%) | catalogued as COSV99547514; called by muse, mutect2
- TTN | c.9663G>T p.V3221= (on ENST00000591111; = p.V3175= on NM_003319.4) | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV60331426; called by muse, mutect2, varscan2
- USP38 | c.3123A>G p.V1041= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as COSV100189355; called by muse, mutect2, varscan2
- LINC00174 | n.3288C>G | RNA (SNP) | VAF 12/71 reads (17%) | called by mutect2, varscan2
